Gene-level copy-number profile of specimen HCM-BROD-0421-C71-85A from HCMI case HCM-BROD-0421-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.7 years (18,165 days).
Specimen HCM-BROD-0421-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4cedf73c-3a68-4b01-ab48-de7e63d6946e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0421-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/d9b09c84-694f-42af-8d71-617e6c726c10

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 645; copy number 3: 3,596; copy number 4: 20,461; copy number 5: 13,283; copy number 6: 13,227; copy number 7: 5,319; copy number 8: 1,567; copy number 9: 68; copy number 10: 45; copy number 11: 29; copy number 12: 4; copy number 13: 3; copy number 20: 8; copy number 53: 1; copy number 55: 33; copy number 56: 7; copy number 58: 19; copy number 62: 2; copy number 63: 3; copy number 65: 22; copy number 66: 5; copy number 98: 3; copy number 103: 17; copy number 111: 19; copy number 112: 4; copy number 113: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 295 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,051,304–56,328,625, 76 genes, copy number 10–13 (within-gene range 7–13) (broad region; genes not listed).
- chr5:191,495–196,341, 2 genes, copy number 9: LRRC14B, AC021087.4.
- chr6:120,462,511–120,781,512, 4 genes, copy number 9: AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3.
- chr8:126,474,189–131,144,948, 60 genes, copy number 53–62: AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1.
- chr8:132,866,958–134,979,279, 42 genes, copy number 20–98: TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.
- chr8:137,105,352–137,105,458, 1 gene, copy number 55: RNU6-144P.
- chr10:60,734,342–61,026,420, 5 genes, copy number 12–13: ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr12:45,444,766–45,610,620, 3 genes, copy number 113: AC063924.1, AC079950.1, U6.
- chr12:52,585,589–52,782,839, 17 genes, copy number 103: KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2.
- chr12:57,723,761–57,896,482, 19 genes, copy number 111 (within-gene range 4–111): AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1.
- chr12:123,233,436–123,283,034, 4 genes, copy number 112 (within-gene range 4–112): C12orf65, CDK2AP1, AC068768.1, RNA5SP375.
- chr14:49,373,966–49,635,244, 14 genes, copy number 9: ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2.
- chr14:49,768,130–49,864,379, 8 genes, copy number 9: KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1.
- chr14:49,927,571–50,105,043, 1 gene, copy number 9 (within-gene range 7–9): LINC01588.
- chr14:50,050,368–50,944,483, 30 genes, copy number 9 (within-gene range 8–9): PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2, AL133485.2, AL133485.1, AL358334.1, PYGL, ABHD12B, AL358334.3.
- chr14:50,975,262–51,385,603, 9 genes, copy number 9: TRIM9, AL358334.4, AL591770.1, TMX1, SNORA70, Y_RNA, LINC00519, LINC00640, AL358332.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
